Gene-level copy-number profile of tumor specimen TCGA-DX-A8BJ-01A from TCGA case TCGA-DX-A8BJ, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant fibrous histiocytoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 76.9 years (28,091 days).
Specimen TCGA-DX-A8BJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.140914c0-8754-4a22-8852-7818697a5d4d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A8BJ-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 827 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f61299c4-60b0-46a8-aae0-ecdb0490e5e0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 92; copy number 1: 1,375; copy number 2: 20,573; copy number 3: 21,646; copy number 4: 13,688; copy number 5: 1,946; copy number 6: 246; copy number 7: 68; copy number 8: 33; copy number 12: 129.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A8BJ-01A-11D-A416-01): tumor purity 0.78, ploidy 2.96, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 92 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:170,178,145–170,813,670, 12 genes (within-gene range 0–3): MYO3B, MYO3B-AS1, HMGB1P4, AC007277.1, AC007277.2, AC007405.1, LINC01124, SP5, EIF2S2P4, AC007405.3, Y_RNA, ERICH2.
- chr2:206,765,357–206,969,474, 4 genes (within-gene range 0–3): FASTKD2, AC008269.1, AC008269.2, CPO.
- chr2:207,529,737–207,769,906, 11 genes: CREB1, METTL21A, RPS29P9, LINC01857, RNU6-664P, PPP1R14BP2, Y_RNA, CCNYL1, AC096772.1, MIR4775, FZD5.
- chr2:207,868,582–207,869,915, 1 gene: AC083900.1.
- chr4:40,743,627–42,402,487, 34 genes: AC131953.2, NSUN7, ARL4AP2, APBB2, AC131953.1, Y_RNA, RNA5SP160, RNU6-836P, RNU6-1195P, UCHL1-AS1, UCHL1, Y_RNA, LIMCH1, RPL12P20, AC108050.1, AC105389.2, OR5M14P, PHOX2B, PHOX2B-AS1, AC105389.1, RNU1-49P, HMGB1P28, LINC00682, AC108210.1, AC108210.2, TMEM33, DCAF4L1, AC106052.1, SLC30A9, ATP1B1P1, BEND4, AC111006.1, AC024022.1, SHISA3.
- chr5:122,311,297–122,479,087, 6 genes: AC113349.2, SNCAIP, AC113349.1, AC119150.1, AC119150.2, MGC32805.
- chr5:123,344,890–123,637,403, 6 genes: CEP120, KRT8P33, HMGB3P17, AC026422.1, CSNK1G3, KRT18P16.
- chr9:21,967,752–23,682,662, 18 genes: CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 230 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:164,921,318–164,980,137, 2 genes, copy number 7: RPL35AP7, RNU6-755P.
- chr2:89,286,689–90,367,699, 52 genes, copy number 7: IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38, IGKV1-39, IGKV2-40, AC006453.3, LSP1P5, 5S_rRNA, AC006453.1, AC006453.2, AC006453.4, IGKV2D-40, IGKV1D-39, IGKV2D-38, IGKV1D-37, IGKV2D-36, IGKV1D-35, IGKV3D-34, IGKV1D-33, IGKV1D-32, IGKV3D-31, IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7.
- chr4:51,843,000–59,630,324, 137 genes, copy number 7–12 (within-gene range 3–12) (broad region; genes not listed).
- chr12:57,674,665–58,395,138, 33 genes, copy number 8: RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1.
- chr12:60,092,864–60,419,293, 6 genes, copy number 7: AC080011.1, AC087883.2, AC087883.1, Y_RNA, AC090022.1, AC090022.2.

Autosomal genes at a single copy (total copy number 1): 1,370. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
